Surgical pathology report (de-identified scan), TCGA case TCGA-O8-A75V, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Saint Mary's Health Care, specimen TCGA-O8-A75V-01A (Primary Tumor).

[page 1 of 3]
Surg Path Final Report

* Final Report *

ICD-O-3

Carcinoma, hepatocellular NOS
817013

* Final Report *

Site: Liver C22.0
JPW 8/21/13

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

Collected:

Accession:

Physician:

PROCEDURE

Robotic assisted liver resection

HISTORY

Hepatocellular carcinoma

GROSS

Received in formalin, labeled "liver resection," is a 4 x 3.5 x 2 cm, 10-gram irregular-shaped portion of liver. It has previously been incised. The surface is partly smooth and mostly roughened. The surgeon has marked the superficial with yellow ink, the deep with red ink, the medial with orange ink, and the lateral with black ink. Ink has spilled into the area where it has been previously incised. Cut section shows a 2.4 x 2.2 x 2 cm tan circumscribed mass. The mass is 0.1 cm to the yellow margin, 0.1 cm or less to the red inked deep margin, 0.2 cm to the orange inked medial margin, and 0.1 cm or less to the black inked lateral margin. The uninvolved liver is tan. Submitted entirely in 10 cassettes.

Tissue is submitted for the TCGA research study per protocol.

Total time in 10% neutral buffered formalin from collection through processing: 21 hours. Total cold ischemia time:

DIAGNOSIS

HEPATOCELLULAR CARCINOMA PROFILE

SPECIMEN TYPE: WEDGE RESECTION.

CLINICAL/WORKING STAGE: N/A

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
~~Surg Path Final Report~~

* Final Report *

TISSUE COLD ISCHEMIA TIME:

TISSUE DURATION IN 10 PERCENT NEUTRAL BUFFERED FORMALIN: 21 HOURS.

TUMOR FOCALITY: SOLITARY.

TUMOR SIZE: 2.4 x 2.2 x 2 CM

HISTOLOGIC TYPE AND GRADE: HEPATOCELLULAR CARCINOMA, TRABECULAR
PATTERN,
GRADE II.

TUMOR EXTENSION: TUMOR IS CONFINED TO THE LIVER.

LYMPH-VASCULAR INVASION: NOT IDENTIFIED.

PERINEURAL INVASION: NOT IDENTIFIED.

MARGINS: THIS IS A LARGELY ENCAPSULATED TUMOR WITH THE TUMOR MARGIN
DEFINED
BY NARROW BAND OF DESMOPLASTIC FIBROUS STROMA. ALL MARGINS ARE
NEGATIVE WITH
THE EXCEPTION THAT THE POSTERIOR MARGIN IS INDETERMINATE DUE TO
ENCROACHMENT
OF THIS MARGIN AFTER EXCISION OF THE TUMOR.

ADDITIONAL PATHOLOGIC FINDINGS: TUMOR IS PRESENT ON A BACKGROUND OF
MICRONODULAR CIRRHOSIS.

DISTANT METASTASIS: NOT APPLICABLE.

CANCER STAGE: pT1, pNX

88307

(Electronic Signature)

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
Surg Path Final Report

* Final Report *

Completed Action Item

* Order by

on

Type:

Surg Path Final Report

Date:

Status:

Auth (Verified)

Title:

SURG PATH FINAL REPORT

Encounter info:

Contributor system:

Printed by:

Printed on:

Page 3 of 3
(End of Report)

Source: NCI Genomic Data Commons file d68d3797-d170-496e-b1bd-59e2427602a3 (TCGA-O8-A75V.F3642560-1DE2-43D1-A8B5-06308AFF325E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).